Somatic mutation profile of tumor specimen C3L-05983-02 (aliquot CPT0429420006) from CPTAC case C3L-05983, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 52.8 years (19,298 days).
Specimen C3L-05983-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3578c0e-fff8-4322-b7a0-6e9703439317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05983-32 (Blood Derived Normal), aliquot CPT0434680005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a34d3fa-5efb-482f-bc85-a915a4452b96

The open-access MAF lists 217 somatic variants for this specimen: 151 protein-altering or splice-affecting, 61 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 61, In Frame Del 6, Nonsense Mutation 5, Frame Shift Del 5, Intron 3, RNA 2, Splice Site 2, Frame Shift Ins 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPL10L | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 58/345 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV53558657, COSV53559010, COSV53561078; called by mutect2, varscan2
- AASS | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780710553; called by mutect2, varscan2
- ADAM18 | c.208T>G p.F70V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1404718839, COSV55846015, COSV55846388; called by mutect2, varscan2
- ATP2B2 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 72/365 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59490835; called by mutect2, varscan2
- ATRX | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs782228142, COSV64883023; called by mutect2, varscan2
- C1QL1 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV99492643; called by mutect2, varscan2
- CACNA2D1 | c.2131T>G p.F711V (on ENST00000356253 / NM_001366867.1; = p.F699V on NM_000722.4) | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62383667; called by mutect2, varscan2
- CADPS | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs151301388; called by mutect2, varscan2
- CARD11 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 55/329 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs772829458, COSV62756776; called by mutect2, varscan2
- CDH11 | c.1460A>C p.K487T | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV51759327, COSV51759358, COSV51764779; called by mutect2, varscan2
- CDH12 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.348); catalogued as rs551198422, COSV66460340; called by mutect2, varscan2
- CHRDL2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.509); catalogued as rs538148268, COSV99734144; called by mutect2, varscan2
- COL1A2 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs759205514, COSV51963452; called by mutect2, varscan2
- CPNE8 | c.1106T>C p.L369P | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1285188515; called by mutect2, varscan2
- CSMD1 | c.7349G>T p.G2450V (on ENST00000520002; = p.G2449V on NM_033225.6) | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.234); catalogued as rs768668221; called by mutect2, varscan2
- CSMD3 | c.1593A>C p.E531D (on ENST00000297405 / NM_001363185.1; = p.E427D on NM_052900.3) | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV52105113, COSV52338075; called by mutect2, varscan2
- CTIF | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56484305; called by mutect2, varscan2
- CYLC1 | c.1163A>C p.K388T | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV61411679, COSV61416457; called by mutect2, varscan2
- DCAF4L1 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs1283722562; called by mutect2, varscan2
- DCAF4L2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 143/514 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1158634102, COSV60478459; called by mutect2, varscan2
- DHX33 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs138164512; called by mutect2, varscan2
- DMD | c.5413del p.V1805* | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | catalogued as CD068545; called by mutect2, pindel, varscan2
- DNAH5 | c.8764C>T p.R2922C | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369455386; called by mutect2, varscan2
- EHMT1 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757192910; called by mutect2, varscan2
- EPHA7 | c.1574A>C p.N525T | Missense Mutation (SNP) | VAF 37/346 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV100993715; called by mutect2, varscan2
- H3Y1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious, low confidence (0.01); catalogued as rs565916700; called by mutect2, varscan2
- H4C3 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 82/504 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV58090617; called by mutect2, varscan2
- HELZ2 | c.7786G>A p.V2596M (on ENST00000467148 / NM_001037335.2; = p.V2027M on NM_033405.3) | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408201017, COSV64442928; called by mutect2, varscan2
- IFT140 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 110/394 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756482228; called by mutect2, varscan2
- INTS6 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 96/397 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs146380686; called by mutect2, varscan2
- KRT72 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as rs184630537, COSV53373081; called by mutect2, varscan2
- LRP1 | c.11233_11235del p.K3745del | In Frame Del (DEL) | VAF 68/356 reads (19%) | catalogued as rs761379473; called by pindel, varscan2
- MUC16 | c.16491G>T p.K5497N | Missense Mutation (SNP) | VAF 52/386 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV67486190; called by mutect2, varscan2
- NEDD1 | c.1887G>A p.M629I | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1430043657; called by mutect2, varscan2
- NEGR1 | c.561T>G p.Y187* | Nonsense Mutation (SNP) | VAF 28/206 reads (14%) | catalogued as COSV60835050; called by mutect2, varscan2
- NTN3 | c.449_451del p.F150del | In Frame Del (DEL) | VAF 44/415 reads (11%) | catalogued as rs749066450; called by pindel, varscan2
- OR51G2 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as COSV58995206; called by mutect2, varscan2
- PCDH18 | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100787295; called by mutect2, varscan2
- PCDHA3 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 90/486 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as rs782560612, COSV63539730; called by mutect2, varscan2
- PCDHB6 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 188/552 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs782083342, COSV50701157; called by mutect2, varscan2
- PCED1B | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs772064186; called by mutect2, varscan2
- PNRC1 | c.301_303del p.K101del | In Frame Del (DEL) | VAF 45/418 reads (11%) | catalogued as rs746966684; called by pindel, varscan2
- PTPRD | c.2858A>G p.K953R | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV61943239; called by mutect2, varscan2
- QKI | c.934+4A>G | Splice Region (SNP) | VAF 38/275 reads (14%) | catalogued as COSV51696404; called by mutect2, varscan2
- RFPL4B | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 60/422 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV71437433; called by mutect2, varscan2
- SCIN | c.1546C>T p.R516W (on ENST00000297029 / NM_001112706.3; = p.R269W on NM_033128.3) | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767783402; called by mutect2, varscan2
- SDK2 | c.2537G>A p.R846Q | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.227); catalogued as COSV66180883; called by mutect2, varscan2
- SEMA6D | c.2060G>A p.R687Q (on ENST00000316364 / NM_153618.2; = p.R625Q on NM_020858.2) | Missense Mutation (SNP) | VAF 60/332 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.892); catalogued as rs370361613; called by mutect2, varscan2
- SIGLEC15 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs1222980147; called by mutect2, varscan2
- SLC29A1 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 52/437 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs78261243, COSV57579639; called by mutect2, varscan2
- SNTG2 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs545016860, COSV57967488; called by mutect2, varscan2
- SORCS1 | c.1793T>G p.V598G | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53885388, COSV53916578; called by mutect2, varscan2
- SV2A | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs769027394, COSV64964133; called by mutect2, varscan2
- THSD7A | c.1542A>C p.E514D | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV101448969, COSV70273041; called by mutect2, varscan2
- TMEM132D | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70601107; called by mutect2, varscan2
- TMEM187 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.168); catalogued as rs1557122855; called by mutect2, varscan2
- TP53 | c.124del p.D42Ifs*2 | Frame Shift Del (DEL) | VAF 103/308 reads (33%) | catalogued as COSV53625330; called by mutect2, pindel, varscan2
- TRIO | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs139892017; called by mutect2, varscan2
- TTN | c.37392G>T p.K12464N (on ENST00000591111; = p.K5040N on NM_003319.4) | Missense Mutation (SNP) | VAF 82/213 reads (38%) | PolyPhen benign (0.135); catalogued as COSV100626700; called by mutect2, varscan2
- TULP4 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 108/567 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as rs1229743903, COSV100893544; called by mutect2, varscan2
- TYK2 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs376427383; ClinVar: uncertain significance; called by mutect2, varscan2
- USH2A | c.7933C>A p.Q2645K | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1297827509, COSV56405323; called by mutect2, varscan2
- ZC3H11B | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 74/138 reads (54%) | catalogued as rs575310558; called by mutect2, varscan2
- ZFHX2 | c.6710C>T p.P2237L | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as rs866596349; called by mutect2, varscan2
- ZNF615 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 84/416 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762696316; called by mutect2, varscan2
- ABCA13 | c.5165C>A p.S1722Y | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- AC138647.1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 63/496 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.728); called by mutect2, varscan2
- ADGRL4 | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.428); called by mutect2, varscan2
- ADNP | c.2847G>A p.M949I | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by mutect2, varscan2
- AKR7L | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by mutect2, varscan2
- ALPK2 | c.4436C>T p.A1479V | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by mutect2, varscan2
- APCDD1 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by mutect2, varscan2
- ARHGAP20 | c.2044_2092del p.T682Gfs*46 | Frame Shift Del (DEL) | VAF 76/548 reads (14%) | called by mutect2, pindel
- ASS1 | c.552C>G p.N184K | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ATP10D | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 42/293 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- C10orf71 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 127/389 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.321); called by mutect2, varscan2
- CADM2 | c.552_575del p.S185_V192del (on ENST00000407528 / NM_001167674.2; = p.S187_V194del on NM_153184.4) | In Frame Del (DEL) | VAF 39/325 reads (12%) | called by mutect2, pindel, varscan2
- CD177 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 56/340 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by mutect2, varscan2
- CENPE | c.7166C>A p.S2389* | Nonsense Mutation (SNP) | VAF 24/156 reads (15%) | called by mutect2, varscan2
- CFAP54 | c.4387A>C p.S1463R | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); called by mutect2, varscan2
- CFH | c.992A>G p.K331R | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); called by mutect2, varscan2
- CNTLN | c.524A>C p.E175A | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.223); called by mutect2, varscan2
- CPAMD8 | c.1775T>G p.L592R (on ENST00000651564; = p.L545R on NM_015692.5) | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- DCLK2 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- DLG2 | c.398A>C p.N133T (on ENST00000650630 / NM_001351274.2; = p.N96T on NM_001142699.3) | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.068); called by mutect2, varscan2
- DLGAP2 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- DNAI4 | c.2127A>C p.K709N | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by mutect2, varscan2
- DNM1L | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- DOP1A | c.1019G>C p.G340A | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.067); called by mutect2, varscan2
- DPYD | c.514A>T p.R172* | Nonsense Mutation (SNP) | VAF 44/280 reads (16%) | called by mutect2, varscan2
- DYSF | c.3595_3598dup p.D1200Vfs*21 | Frame Shift Ins (INS) | VAF 52/413 reads (13%) | called by mutect2, pindel, varscan2
- EBF4 | c.751_757+23del p.X251_splice (on ENST00000609451; = p.X247_splice on NM_001110514.1) | Splice Site (DEL) | VAF 40/185 reads (22%) | called by mutect2, pindel, varscan2
- ERICH3 | c.3074G>T p.C1025F | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.481); called by mutect2, varscan2
- FAM184A | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by mutect2, varscan2
- FAT4 | c.6057A>C p.Q2019H | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- FAT4 | c.11216C>G p.A3739G | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by mutect2, varscan2
- FLRT2 | c.585A>G p.I195M | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- FLVCR2 | c.1060G>C p.V354L | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by mutect2, varscan2
- FOXD4L5 | c.905A>G p.H302R | Missense Mutation (SNP) | VAF 134/723 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); called by mutect2, varscan2
- HCN1 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by mutect2, varscan2
- HDX | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by mutect2, varscan2
- IGHV3-35 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.304); called by mutect2, varscan2
- ITM2A | c.709A>C p.N237H | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by mutect2, varscan2
- KCNN2 | c.404G>A p.S135N (on ENST00000264773; = p.S347N on NM_021614.4) | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- KHDRBS2 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by mutect2, varscan2
- LRP2 | c.5260C>G p.H1754D | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by mutect2, varscan2
- LRRC23 | c.956G>C p.R319P | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- LRRC37B | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 63/360 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- LRRK2 | c.4210A>G p.T1404A | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by mutect2, varscan2
- LRRK2 | c.6965A>C p.K2322T | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.357); called by mutect2, varscan2
- MAMSTR | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by mutect2, varscan2
- MBOAT4 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- MEI1 | c.1315A>C p.T439P | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.203); called by mutect2, varscan2
- MFSD11 | c.376A>G p.N126D | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by mutect2, varscan2
- MUC5B | c.640_641delinsA p.P214Rfs*13 | Frame Shift Del (DEL) | VAF 56/354 reads (16%) | called by pindel, varscan2*
- MUC5B | c.1540+2_1540+18del p.X514_splice | Splice Site (DEL) | VAF 43/307 reads (14%) | called by mutect2, pindel, varscan2
- MYBPC2 | c.231_242del p.K78_P81del | In Frame Del (DEL) | VAF 38/323 reads (12%) | called by mutect2, pindel, varscan2
- NFAT5 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.162); called by mutect2, varscan2
- NXPH1 | c.280T>C p.S94P | Missense Mutation (SNP) | VAF 61/445 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.251); called by mutect2, varscan2
- OLR1 | c.180_188del p.Q62_S64del | In Frame Del (DEL) | VAF 28/195 reads (14%) | called by mutect2, pindel, varscan2
- OR5V1 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by mutect2, varscan2
- PCDH15 | c.1691T>G p.L564R | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.147); called by mutect2, varscan2
- PCNP | c.389T>C p.M130T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by mutect2, varscan2
- PIK3C3 | c.1538C>A p.T513N | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by mutect2, varscan2
- PIP5KL1 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- POM121L12 | c.814A>C p.T272P | Missense Mutation (SNP) | VAF 62/440 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by mutect2, varscan2
- POSTN | c.1429A>G p.S477G | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PRDM6 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by mutect2, varscan2
- RBM24 | c.486_488dup p.A172dup (on ENST00000379052 / NM_001143942.2; = p.A127dup on NM_153020.2) | In Frame Ins (INS) | VAF 39/271 reads (14%) | called by mutect2, varscan2
- RIT2 | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by mutect2, varscan2
- RND3 | c.170T>A p.F57Y | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by mutect2, varscan2
- ROBO1 | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RPTOR | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by mutect2, varscan2
- RSKR | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 64/362 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.048); called by mutect2, varscan2
- RUFY3 | c.1770T>G p.N590K | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by mutect2, varscan2
- RUNX1T1 | c.1207A>C p.K403Q (on ENST00000265814 / NM_001198628.1; = p.K376Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/396 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.83); called by mutect2, varscan2
- SAMD9 | c.3562C>T p.R1188W | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by mutect2, varscan2
- SCN11A | c.2053C>A p.P685T | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SORT1 | c.2109_2110del p.Y704Rfs*113 | Frame Shift Del (DEL) | VAF 48/330 reads (15%) | called by mutect2, pindel, varscan2
- TEX13C | c.792G>T p.M264I | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by mutect2, varscan2
- TMEM232 | c.1814A>T p.K605M | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by mutect2, varscan2
- TNRC18 | c.5348C>A p.A1783E | Missense Mutation (SNP) | VAF 68/666 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.082); called by mutect2, varscan2
- TREML2 | c.466G>C p.G156R | Missense Mutation (SNP) | VAF 56/402 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by mutect2, varscan2
- TRPS1 | c.2034A>T p.E678D (on ENST00000220888 / NM_001330599.2; = p.E691D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by mutect2, varscan2
- UGT2A3 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 24/204 reads (12%) | called by mutect2, varscan2
- USP26 | c.1832A>C p.K611T | Missense Mutation (SNP) | VAF 113/195 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by mutect2, varscan2
- ZAN | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 92/494 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by mutect2, varscan2
- ZNF208 | c.1330A>C p.K444Q | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ZNF208 | c.1204T>A p.C402S | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ZNF696 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 148/584 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZNF839 | c.1598A>G p.N533S (on ENST00000558850 / NM_001267827.1; = p.N649S on NM_018335.5) | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.023); called by mutect2, varscan2
- ABCG1 | c.1680G>A p.T560= | Silent (SNP) | VAF 40/280 reads (14%) | catalogued as rs372146956, COSV100494174; called by mutect2, varscan2
- ANKRD65 | c.277C>T p.L93= | Silent (SNP) | VAF 63/337 reads (19%) | catalogued as rs570670674, COSV70987248; called by mutect2, varscan2
- ARID1B | c.6465G>A p.T2155= | Silent (SNP) | VAF 64/408 reads (16%) | catalogued as rs377350616, COSV99267427; ClinVar: likely benign; called by mutect2, varscan2
- BARD1 | c.1152C>T p.S384= | Silent (SNP) | VAF 46/379 reads (12%) | catalogued as rs368291318; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by mutect2, varscan2
- CACNA1F | c.5433G>A p.Q1811= | Silent (SNP) | VAF 60/142 reads (42%) | called by mutect2, varscan2
- CDH2 | c.1293C>T p.F431= | Silent (SNP) | VAF 52/339 reads (15%) | catalogued as rs771635033, COSV52280868; called by mutect2, varscan2
- CDH8 | c.1830C>T p.V610= | Silent (SNP) | VAF 39/342 reads (11%) | catalogued as rs766269925, COSV54883946; called by mutect2, varscan2
- CEP170 | c.4653C>T p.A1551= | Silent (SNP) | VAF 36/266 reads (14%) | catalogued as rs200812345; called by mutect2, varscan2
- CLMP | c.855G>A p.V285= | Silent (SNP) | VAF 58/310 reads (19%) | called by mutect2, varscan2
- CPXM2 | c.168C>T p.T56= | Silent (SNP) | VAF 64/356 reads (18%) | catalogued as rs763728087; called by mutect2, varscan2
- CTRB1 | c.429C>T p.S143= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1468539864; called by mutect2, varscan2
- DLG4 | c.990C>T p.G330= (on ENST00000399506 / NM_001321075.3; = p.G373= on NM_001365.4) | Silent (SNP) | VAF 158/426 reads (37%) | called by mutect2, varscan2
- DLGAP2 | c.1920C>T p.D640= | Silent (SNP) | VAF 78/436 reads (18%) | catalogued as rs373983764; called by mutect2, varscan2
- DMD | c.5221T>C p.L1741= | Silent (SNP) | VAF 65/180 reads (36%) | catalogued as rs1228749524, COSV63747107, COSV63789783; called by mutect2, varscan2
- DMXL1 | c.2340G>A p.K780= | Silent (SNP) | VAF 19/164 reads (12%) | called by mutect2, varscan2
- DPYSL3 | c.588A>G p.Q196= | Silent (SNP) | VAF 122/303 reads (40%) | called by mutect2, varscan2
- FAM83H | c.2259C>T p.G753= | Silent (SNP) | VAF 170/754 reads (23%) | catalogued as rs1210132008; called by mutect2, varscan2
- FOXC2 | c.1005G>A p.A335= | Silent (SNP) | VAF 34/227 reads (15%) | called by mutect2, varscan2
- FOXG1 | c.105G>A p.A35= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as rs753859771; called by mutect2, varscan2
- GUCY1B1 | c.81A>G p.K27= | Silent (SNP) | VAF 18/128 reads (14%) | called by mutect2, varscan2
- HCFC1R1 | c.135G>C p.R45= | Silent (SNP) | VAF 96/358 reads (27%) | called by mutect2, varscan2
- HDGF | c.654G>A p.E218= | Silent (SNP) | VAF 78/343 reads (23%) | called by mutect2, varscan2
- HEPACAM | c.1089C>T p.R363= | Silent (SNP) | VAF 80/482 reads (17%) | called by mutect2, varscan2
- HMCN1 | c.12135C>A p.I4045= | Silent (SNP) | VAF 35/280 reads (13%) | called by mutect2, varscan2
- IQUB | c.2364G>A p.R788= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as rs1317318776; called by mutect2, varscan2
- LEFTY1 | c.168C>T p.H56= | Silent (SNP) | VAF 73/480 reads (15%) | catalogued as rs140535323; called by mutect2, varscan2
- LRFN5 | c.282T>G p.A94= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as COSV53260262, COSV99984883; called by mutect2, varscan2
- MCHR2 | c.576C>T p.D192= | Silent (SNP) | VAF 28/208 reads (13%) | catalogued as rs201955415, COSV56001330; called by mutect2, varscan2
- MDFIC | c.249T>G p.T83= | Silent (SNP) | VAF 54/295 reads (18%) | called by mutect2, varscan2
- MTCL1 | c.2529G>A p.G843= (on ENST00000306329 / NM_001378206.1; = p.G483= on NM_015210.4) | Silent (SNP) | VAF 82/420 reads (20%) | called by mutect2, varscan2
- MYH3 | c.990G>T p.L330= | Silent (SNP) | VAF 32/230 reads (14%) | called by mutect2, varscan2
- NEB | c.9327C>T p.D3109= | Silent (SNP) | VAF 125/343 reads (36%) | called by mutect2, varscan2
- NEDD1 | c.993T>C p.A331= | Silent (SNP) | VAF 43/301 reads (14%) | called by mutect2, varscan2
- OPRM1 | c.24G>A p.T8= | Silent (SNP) | VAF 70/418 reads (17%) | catalogued as rs1799973, COSV57680444; called by mutect2, varscan2
- OR4C15 | c.1086T>C p.S362= (on ENST00000314644; = p.S308= on NM_001001920.2) | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV100115955; called by mutect2, varscan2
- OR5T3 | c.108A>G p.Q36= | Silent (SNP) | VAF 54/354 reads (15%) | catalogued as COSV100282856, COSV57379534; called by mutect2, varscan2
- OTUD5 | c.66G>T p.P22= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV50240313; called by mutect2, varscan2
- PCDH18 | c.1758A>G p.A586= | Silent (SNP) | VAF 49/331 reads (15%) | called by mutect2, varscan2
- PCLO | c.1941C>T p.G647= | Silent (SNP) | VAF 44/293 reads (15%) | catalogued as rs190242317, COSV61644369; called by mutect2, varscan2
- PDE1C | c.96C>T p.R32= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as rs756223082, COSV58507546; called by mutect2, varscan2
- PFKFB3 | c.189C>T p.G63= | Silent (SNP) | VAF 42/210 reads (20%) | catalogued as rs912136914; called by mutect2, varscan2
- PKDREJ | c.5916C>A p.L1972= | Silent (SNP) | VAF 66/194 reads (34%) | called by mutect2, varscan2
- PKHD1L1 | c.12189T>A p.T4063= | Silent (SNP) | VAF 31/301 reads (10%) | called by mutect2, varscan2
- PLXNB1 | c.678C>T p.A226= | Silent (SNP) | VAF 146/389 reads (38%) | catalogued as rs1203163029; called by mutect2, varscan2
- PROP1 | c.198G>A p.P66= | Silent (SNP) | VAF 166/415 reads (40%) | catalogued as rs769315766, COSV57644591; called by mutect2, varscan2
- SALL3 | c.2394C>T p.D798= | Silent (SNP) | VAF 66/455 reads (15%) | catalogued as rs547166722; called by mutect2, varscan2
- SEPTIN3 | c.258C>A p.G86= | Silent (SNP) | VAF 76/264 reads (29%) | called by mutect2, varscan2
- SIGLEC5 | c.516G>A p.A172= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs1245923488, COSV55778747; called by mutect2, varscan2
- SNX5 | c.741C>T p.T247= | Silent (SNP) | VAF 53/228 reads (23%) | catalogued as rs372550237; called by mutect2, varscan2
- SUN1 | c.2235C>T p.S745= (on ENST00000405266 / NM_001367651.1; = p.S625= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 44/270 reads (16%) | catalogued as rs376370215; called by mutect2, varscan2
- TBX2 | c.192G>C p.A64= | Silent (SNP) | VAF 9/67 reads (13%) | called by mutect2, varscan2
- TDRKH | c.33G>A p.L11= | Silent (SNP) | VAF 44/298 reads (15%) | called by mutect2, varscan2
- TEX15 | c.4605G>A p.P1535= (on ENST00000256246; = p.P1918= on NM_001350162.2) | Silent (SNP) | VAF 44/254 reads (17%) | catalogued as rs754384901, COSV56345696; called by mutect2, varscan2
- TFAP2A | c.135G>A p.P45= (on ENST00000482890; = p.P37= on NM_001032280.3) | Silent (SNP) | VAF 57/311 reads (18%) | called by mutect2, varscan2
- TRAV25 | c.189T>C p.F63= | Silent (SNP) | VAF 65/316 reads (21%) | called by mutect2, varscan2
- TRPC4 | c.402G>A p.K134= | Silent (SNP) | VAF 26/250 reads (10%) | catalogued as rs1369056516; called by mutect2, varscan2
- TUSC3 | c.945C>T p.C315= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as rs1001945795; called by mutect2, varscan2
- UBE3C | c.2910C>T p.P970= | Silent (SNP) | VAF 37/218 reads (17%) | called by mutect2, varscan2
- ZFPM2 | c.2403T>G p.T801= | Silent (SNP) | VAF 116/447 reads (26%) | catalogued as rs1291476866, COSV101023176; called by mutect2, varscan2
- ZNF229 | c.150G>T p.L50= | Silent (SNP) | VAF 50/266 reads (19%) | called by mutect2, varscan2
- ZNF70 | c.189C>T p.Y63= | Silent (SNP) | VAF 76/386 reads (20%) | catalogued as rs139400336; called by mutect2, varscan2
- CLEC7A | c.202+193C>A | Intron (SNP) | VAF 37/212 reads (17%) | called by mutect2, varscan2
- DCHS2 | n.1514A>C | RNA (SNP) | VAF 71/407 reads (17%) | called by mutect2, varscan2
- OSTF1P1 | n.503G>C | RNA (SNP) | VAF 46/273 reads (17%) | called by mutect2, varscan2
- SUCLG2 | c.1063-8133G>A | Intron (SNP) | VAF 52/292 reads (18%) | called by mutect2, varscan2
- UNC5D | c.104-4764T>G | Intron (SNP) | VAF 30/194 reads (15%) | catalogued as COSV99779854; called by mutect2, varscan2
